Somatic mutation profile of tumor specimen TARGET-20-PARPEK-09A (aliquot TARGET-20-PARPEK-09A-01D) from TARGET case TARGET-20-PARPEK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.5 years (174 days).
Specimen TARGET-20-PARPEK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48fd3f7e-8150-4b61-af21-d5566877af14.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPEK-14A (Bone Marrow Normal), aliquot TARGET-20-PARPEK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a304e6e-87ba-45fd-a4d9-767824253c8b

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- P2RY2 | c.636C>T p.A212= | Silent (SNP) | VAF 56/181 reads (31%) | catalogued as rs772692364, COSV60776088; called by muse, mutect2, varscan2
